Somatic mutation profile of tumor specimen 0DWYWT from CCDI case PBCPDW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 15.1 years (5,506 days).
Specimen 0DWYWT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bb4419b-4941-4833-956d-f1bf68623d82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWYUR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f9001cd-f7bc-4414-b50a-be92dc1e2083

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCLK1 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 56/486 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55174019; called by muse, mutect2, varscan2
- MYO5C | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 76/186 reads (41%) | catalogued as rs199686118; called by muse, mutect2, varscan2
- RASGRP2 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 100/346 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs770760594, COSV100818170, COSV62450617; called by muse, mutect2, varscan2
- EIF4A1 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- EIF4G2 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 168/562 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- FBXL17 | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 102/328 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR1I3 | c.-16C>T | 5'UTR (SNP) | VAF 38/489 reads (8%) | called by muse, mutect2
